TARGET case TARGET-30-PASYPX — Neuroblastoma (TARGET-NBL)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neuroepitheliomatous Neoplasms; Primary site: Other and ill-defined sites. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/9387e780-2e30-587b-b3d1-e18f76ef94ce

Demographics
Sex at birth: female; Race: white; Ethnicity: hispanic or latino; Age at index: 4 years; Vital status: Alive.

Diagnoses (1)
1. Neuroblastoma, NOS: ICD-O-3 morphology code: 9500/3; ICD-10 code: C76.2; Tissue or organ of origin: Abdomen, NOS; Classification of tumor: primary; Age at diagnosis: 4.1 years (1,514 days); Year of diagnosis: 2009; Days to last follow up: 3,180 days (8.7 years); Cog neuroblastoma risk group: High Risk; Inpc grade: Undifferentiated or Poorly Differentiated; INSS stage: Stage 4; Mitosis karyorrhexis index: Intermediate.
   Pathology details: Necrosis percent: 15.
   Treatment given: Protocol identifier: ANBL0532.
   Treatment given: Protocol identifier: ANBL00B1.

Follow-up (2 entries)
- Days to follow up: 296 days; Progression or recurrence anatomic site: Bone marrow; Days to first event: 296 days; First event: Progression.
- Days to follow up: 3,180 days (8.7 years); Year of follow up: 2018.

Molecular and laboratory tests
- MYCN amplification: Not Amplified.
- Test: Abnormal, NOS; Ploidy: Hyperdiploid.

Biospecimens (2 samples)
- Sample TARGET-30-PASYPX-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
- Sample TARGET-30-PASYPX-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the TARGET clinical supplement workbook TARGET_NBL_ClinicalData_Discovery_20230523.xlsx (sheet Clinical Data):
- Overall Survival Time in Days: 3180
- Protocol: ANBL00B1, ANBL0532
- Ploidy: Hyperdiploid (DI>1)
- Ploidy Value: 1.16
- Histology: Unfavorable
- ICDO Description: Abdomen, NOS Abdominal wall, NOS Intra-abdominal site, NOS
- Percent Tumor: 97-98
